Gene-level copy-number profile of tumor specimen ALCH-AEEH-TTP1-A from ALCHEMIST case ALCH-AEEH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.3 years (22,381 days).
Specimen ALCH-AEEH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a8ad7f4a-f752-4472-8941-dff54a430c13.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEEH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/5ac8ac15-6b91-468e-a016-4947bd98f00b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 124; copy number 1: 5,428; copy number 2: 52,240; copy number 3: 970; copy number 4: 94; copy number 5: 1; copy number 6: 1; copy number 7: 12; copy number 8: 19; copy number 10: 2; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 94 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–7,694,844, 1 gene (within-gene range 0–2): AL359881.3.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr1:16,124,337–16,156,069, 1 gene (within-gene range 0–1): EPHA2.
- chr1:200,969,390–201,023,714, 1 gene: KIF21B.
- chr2:72,129,238–72,148,038, 1 gene: CYP26B1.
- chr2:130,129,621–130,145,134, 2 genes: MED15P9, CCDC74B.
- chr2:131,527,675–131,536,988, 2 genes: CCDC74A, MED15P4.
- chr2:231,362,708–231,362,793, 1 gene (within-gene range 0–2): MIR4777.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr5:470,456–524,449, 2 genes (within-gene range 0–2): SLC9A3, SLC9A3-AS1.
- chr5:1,510,762–1,510,856, 1 gene (within-gene range 0–2): MIR6075.
- chr5:1,877,413–1,887,236, 2 genes: IRX4, IRX4-AS1.
- chr5:7,289,891–7,326,609, 2 genes (within-gene range 0–2): AC091951.3, AC091951.1.
- chr5:123,636,110–123,637,403, 1 gene: KRT18P16.
- chr7:43,926,436–44,019,175, 7 genes (within-gene range 0–2): UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1.
- chr7:44,013,562–44,019,170, 1 gene (within-gene range 0–2): POLR2J4.
- chr8:43,539,137–43,544,057, 3 genes: AC134698.5, CYP4F44P, AC134698.2.
- chr9:33,441,156–33,473,930, 4 genes: AQP3, AL356218.1, NOL6, MIR6851.
- chr10:86,935,540–86,971,311, 4 genes (within-gene range 0–2): MMRN2, AC025268.1, SNCG, ADIRF-AS1.
- chr11:73,376,399–73,397,474, 2 genes: RELT, AP000763.4.
- chr12:47,784,923–47,788,971, 2 genes (within-gene range 0–2): AC004466.1, AC004466.3.
- chr12:132,424,504–132,425,208, 1 gene: AC148476.1.
- chr15:75,195,643–75,234,834, 4 genes: C15orf39, AC113208.4, AC113208.5, AC113208.3.
- chr15:75,674,322–75,712,848, 3 genes (within-gene range 0–2): CSPG4, AC105020.4, AC105020.1.
- chr15:77,043,680–77,045,160, 1 gene (within-gene range 0–2): AC090181.1.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr16:2,106,669–2,113,342, 2 genes (within-gene range 0–1): MIR6511B1, AC009065.6.
- chr16:28,258,686–28,323,849, 3 genes: AC138904.3, SBK1, AC138904.1.
- chr16:83,929,796–83,931,223, 1 gene (within-gene range 0–2): AC009119.2.
- chr17:47,694,081–47,712,050, 1 gene: TBKBP1.
- chr17:49,914,403–49,932,918, 1 gene: AC027801.4.
- chr17:78,532,813–78,533,055, 1 gene (within-gene range 0–1): RN7SL454P.
- chr17:81,110,487–81,166,221, 6 genes (within-gene range 0–2): AATK, MIR657, MIR3065, MIR338, MIR1250, AC115099.1.
- chr17:82,018,702–82,098,294, 10 genes: CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN.
- chr18:37,273,706–37,306,333, 2 genes (within-gene range 0–2): AC090386.1, AC090386.2.
- chr19:17,933,015–17,943,991, 1 gene: CCDC124.
- chr20:62,663,019–62,666,724, 1 gene (within-gene range 0–2): SLCO4A1-AS1.
- chr21:9,053,122–9,083,101, 2 genes (within-gene range 0–2): CR392039.4, SOWAHCP2.
- chr22:21,207,973–21,227,637, 1 gene (within-gene range 0–2): GGT2.
- chr22:30,239,194–30,289,622, 6 genes (within-gene range 0–2): LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 37 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes, copy number 10: AC239859.2, LINC02799.
- chr12:38,078,529–38,274,549, 10 genes, copy number 8: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA.
- chr12:53,816,185–53,816,479, 1 gene, copy number 11: RN7SKP289.
- chr12:56,376,818–56,596,193, 12 genes, copy number 7 (within-gene range 2–7): APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2, HSPD1P4, RBMS2, RNU6-343P.
- chr12:57,723,761–57,742,157, 1 gene, copy number 8 (within-gene range 2–8): AGAP2.
- chr12:57,738,013–57,797,554, 8 genes, copy number 8 (within-gene range 2–8): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3.
- chr19:1,852,382–1,853,622, 1 gene, copy number 11 (within-gene range 3–11): AC012615.3.
- chr21:43,092,956–43,115,709, 2 genes, copy number 5–6: U2AF1, MRPL51P2.

Autosomal genes at a single copy (total copy number 1): 2,616. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
